Gene-level copy-number profile of tumor specimen TCGA-56-8503-01A from TCGA case TCGA-56-8503, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 76.9 years (28,095 days).
Specimen TCGA-56-8503-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.26dea7d9-fa10-4230-901f-f395440154b7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-56-8503-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8c0bc723-09ad-409a-b8fb-ea907c3232ae

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 629; copy number 1: 18,947; copy number 2: 34,873; copy number 3: 3,526; copy number 4: 1,772; copy number 5: 48; copy number 7: 4; copy number 8: 2; copy number 9: 12; copy number 10: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-56-8503-01A-11D-2391-01): tumor purity 0.22, ploidy 1.59, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 629 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,096–540,200, 22 genes: BNIP3P41, ZNF595, AC253576.1, ZNF718, AC253576.2, AC108475.1, ZNF876P, AC079140.3, AC079140.5, ZNF732, AC079140.6, AC079140.4, ZNF141, AC079140.1, AC079140.2, MIR571, AC092574.2, ZNF519P4, AC092574.1, ABCA11P, ZNF721, PIGG.
- chr4:171,812,254–190,092,279, 264 genes (within-gene range 0–2) (broad region; genes not listed).
- chr8:150,584–4,994,972, 61 genes (within-gene range 0–2) (broad region; genes not listed).
- chr10:44,712–4,515,244, 73 genes (broad region; genes not listed).
- chr10:36,432,882–36,626,138, 6 genes: MTND5P17, MTND4P18, AL590730.1, AL590730.2, NAMPTP1, Y_RNA.
- chr11:5,544,489–5,644,398, 9 genes: OR52H1, OR52H2P, OR52B5P, OR52T1P, HNRNPA1P53, OR52B6, TRIM6, TRIM6-TRIM34, TRIM34.
- chr13:18,467,172–25,366,155, 193 genes (broad region; genes not listed).
- chr13:25,517,119–25,517,225, 1 gene: RNU6-78P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 66 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:187,120,948–190,892,429, 48 genes, copy number 5: RPL39L, AC007920.1, RTP1, MASP1, AC007920.2, RTP4, AC068299.2, AC068299.1, LINC02041, SST, RTP2, AC072022.1, BCL6, AC072022.2, AC108681.1, AC068295.1, LINC01991, AC092941.1, AC092941.2, AC022498.1, LPP-AS2, LPP, FLJ42393, LPP-AS1, MIR28, TPRG1-AS1, TPRG1, AC009319.1, TPRG1-AS2, TP63, AC078809.1, MIR944, P3H2, MTAPP2, P3H2-AS1, RNU6-1109P, NMNAT1P3, CLDN1, CLDN16, TMEM207, IL1RAP, GCNT1P3, RN7SKP296, AC108747.1, LINC02013, CCT6P4, AC092952.1, GMNC.
- chr4:10,167,159–10,295,579, 9 genes, copy number 9: AC006499.6, AC006499.1, AC006499.8, RAF1P1, AC006499.4, AC006499.2, AC006499.3, AC006499.5, AC006499.7.
- chr4:77,157,207–77,433,388, 4 genes, copy number 8–10 (within-gene range 2–10): CCNG2, AC008638.3, AC008638.2, AC008638.1.
- chr8:139,508,701–139,508,971, 1 gene, copy number 8: AC090093.1.
- chr12:114,077,133–114,113,489, 4 genes, copy number 7: AC010183.1, AC010183.2, HAUS8P1, GLULP5.

Autosomal genes at a single copy (total copy number 1): 17,039. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
